Somatic mutation profile of tumor specimen TCGA-B9-A69E-01A (aliquot TCGA-B9-A69E-01A-11D-A31X-10) from TCGA case TCGA-B9-A69E, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 71.7 years (26,198 days).
Specimen TCGA-B9-A69E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dd55774-93d1-4bd0-8015-1a4921976928.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-A69E-10A (Blood Derived Normal), aliquot TCGA-B9-A69E-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32f1027d-8602-46b8-bcc0-94d2ab283022

The open-access MAF lists 88 somatic variants for this specimen: 76 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 58, Silent 12, Frame Shift Del 6, Frame Shift Ins 4, Splice Site 2, Splice Region 2, Nonstop Mutation 1, In Frame Del 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNE2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as rs199473367, CM003450, COSV51710393; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADA | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV63069067; called by muse, mutect2, varscan2
- AMOTL2 | c.1836T>G p.N612K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.918); catalogued as COSV51439919; called by muse, mutect2, varscan2
- AP4E1 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV55918370; called by muse, mutect2, varscan2
- APOBEC3B | c.794T>G p.L265W | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100213724; called by muse, mutect2, varscan2
- ATP7B | c.4097T>C p.V1366A | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD033178, COSV54440689; called by muse, mutect2, varscan2
- ATPAF2 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV58264657; called by muse, mutect2, varscan2
- BICDL2 | c.1238A>T p.K413M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV50187886; called by muse, mutect2, varscan2
- BPIFB6 | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV62755915; called by muse, mutect2, varscan2
- CBLC | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.582); catalogued as COSV54324195; called by muse, mutect2
- CDH1 | c.1566A>C p.T522= | Splice Region (SNP) | VAF 22/88 reads (25%) | catalogued as COSV55736430; called by muse, mutect2, varscan2
- CDH12 | c.2065A>G p.I689V | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV66423129; called by muse, mutect2, varscan2
- CENPF | c.8237T>C p.I2746T | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65276512; called by muse, mutect2, varscan2
- CPNE7 | c.585T>A p.I195= | Splice Region (SNP) | VAF 27/97 reads (28%) | catalogued as COSV52014210; called by muse, mutect2, varscan2
- DLGAP5 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.078); catalogued as COSV55964106; called by muse, mutect2, varscan2
- DNAJC25 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV57957243; called by muse, mutect2, varscan2
- DST | c.1982G>A p.S661N (on ENST00000361203 / NM_001374722.1; = p.S335N on NM_001723.6) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as rs749680270, COSV55025654; called by muse, mutect2, varscan2
- ELP5 | c.331T>C p.C111R | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs1260842543, COSV59708920; called by muse, mutect2, varscan2
- ENKUR | c.114C>A p.D38E | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58632726, COSV58633949; called by muse, mutect2, varscan2
- FAM91A1 | c.771G>C p.K257N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58237123, COSV58238214; called by muse, mutect2
- FANCM | c.3195C>G p.C1065W | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV57503364; called by muse, mutect2, varscan2
- FAT1 | c.12730G>C p.D4244H | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV71675005; called by muse, mutect2, varscan2
- GBF1 | c.202T>G p.F68V | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64146766; called by muse, mutect2, varscan2
- HK1 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV53861480; called by muse, mutect2, varscan2
- HS2ST1 | c.1069T>C p.*357Rext*2 | Nonstop Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV63351457; called by muse, mutect2
- KIF2A | c.1642A>T p.N548Y | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV66946074; called by muse, mutect2, varscan2
- LRP4 | c.4270G>C p.G1424R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.233); catalogued as COSV66137087; called by muse, mutect2, varscan2
- LRPPRC | c.4016C>T p.A1339V | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs760961765, COSV53240432; called by muse, mutect2, varscan2
- LRPPRC | c.4015G>C p.A1339P | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53240442; called by muse, mutect2, varscan2
- LSM1 | c.116-1del p.X39_splice | Splice Site (DEL) | VAF 29/129 reads (22%) | catalogued as COSV100258376; called by mutect2, pindel, varscan2
- MED12L | c.5396T>G p.I1799S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV56386455; called by muse, mutect2, varscan2
- MLLT10 | c.1654T>A p.C552S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV56999829; called by muse, mutect2, varscan2
- MRI1 | c.1040A>T p.E347V (on ENST00000040663 / NM_001031727.4; = p.E300V on NM_032285.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs761701927, COSV50004784; called by muse, mutect2, varscan2
- MRPL3 | c.707C>A p.T236N | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53915272; called by muse, mutect2, varscan2
- MUC4 | c.2108G>T p.G703V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV62165759; called by muse, mutect2, varscan2
- MUC7 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 122/488 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.849); catalogued as COSV100512254; called by muse, mutect2, varscan2
- OBSCN | c.15462G>A p.M5154I | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs780766258, COSV52796013; called by muse, mutect2, varscan2
- OR10G9 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100901554; called by muse, mutect2, varscan2
- OR4A15 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 37/122 reads (30%) | catalogued as rs150217199, COSV100123812; called by muse, mutect2, varscan2
- OR52M1 | c.649A>T p.I217F | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64172297; called by muse, mutect2, varscan2
- PKM | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58790061; called by muse, mutect2, varscan2
- PRKACA | c.416T>C p.F139S | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58068959; called by muse, mutect2, varscan2
- RABIF | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs919986734, COSV66131345; called by muse, mutect2, varscan2
- RIC3 | c.778G>A p.E260K (on ENST00000309737 / NM_001206671.4; = p.E259K on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV58303138; called by muse, mutect2, varscan2
- RIMS1 | c.2305C>G p.L769V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1034032319, COSV53467555; called by muse, mutect2, varscan2
- ROBO2 | c.3713A>T p.D1238V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV59923133, COSV59948346; called by muse, mutect2, varscan2
- SAFB | c.1316C>T p.T439I | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1342503230, COSV52652519; called by muse, mutect2, varscan2
- SIRPA | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 71/259 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs913702063, COSV100605121; called by muse, mutect2, varscan2
- SLC25A36 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV60782484; called by muse, mutect2, varscan2
- SPTA1 | c.1814del p.A605Efs*12 | Frame Shift Del (DEL) | VAF 17/77 reads (22%) | catalogued as COSV63759852; called by mutect2, pindel, varscan2
- SYNPO2 | c.2935T>A p.F979I | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV61113915; called by muse, mutect2, varscan2
- TAOK3 | c.691T>A p.Y231N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66826761; called by muse, mutect2, varscan2
- TENM3 | c.212C>A p.A71E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.255); catalogued as COSV69304264; called by muse, mutect2, varscan2
- TENT5B | c.635T>A p.F212Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56692600, COSV56693385; called by muse, mutect2, varscan2
- THSD7A | c.2548G>A p.V850M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs199705914; called by muse, mutect2, varscan2
- TLR10 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58301255; called by muse, mutect2, varscan2
- TMC5 | c.1179G>T p.Q393H (on ENST00000396229 / NM_001105248.1; = p.Q147H on NM_024780.5) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV54906634, COSV99572955; called by muse, varscan2
- TMEM67 | c.1603G>C p.A535P | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60041897; called by muse, mutect2, varscan2
- TTPAL | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52829308; called by muse, mutect2, varscan2
- TUT4 | c.4291C>A p.Q1431K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV57116530, COSV99932321; called by muse, mutect2, varscan2
- USP9X | c.3440C>T p.A1147V | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV61071776; called by muse, mutect2, varscan2
- ZNF606 | c.2348A>G p.Q783R | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV58706966; called by muse, mutect2, varscan2
- ZNF75A | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs1357107382, COSV73039655; called by muse, mutect2, varscan2
- AK9 | c.752del p.T251Ifs*2 | Frame Shift Del (DEL) | VAF 28/107 reads (26%) | called by mutect2, pindel, varscan2
- DOK7 | c.384_388dup p.T130Rfs*118 | Frame Shift Ins (INS) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- EFCAB13 | c.1655dup p.C552Wfs*11 | Frame Shift Ins (INS) | VAF 89/311 reads (29%) | called by mutect2, varscan2
- FAAP24 | c.251dup p.N84Kfs*3 | Frame Shift Ins (INS) | VAF 40/174 reads (23%) | called by mutect2, pindel, varscan2
- GPR174 | c.372del p.R125Afs*19 | Frame Shift Del (DEL) | VAF 78/130 reads (60%) | called by mutect2, varscan2
- GPR85 | c.631_633del p.D211del | In Frame Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- KCNJ15 | c.467_470del p.I156Rfs*40 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | called by pindel, varscan2
- KIR3DL2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRBA | c.7708_7726+1del p.X2570_splice | Splice Site (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- NDC80 | c.1739del p.N580Ifs*7 | Frame Shift Del (DEL) | VAF 30/151 reads (20%) | called by mutect2, pindel, varscan2
- POLDIP2 | c.1032del p.F344Lfs*76 | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | called by mutect2, pindel, varscan2
- RBM28 | c.1610_1612dup p.G537_Q538insR | In Frame Ins (INS) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- SRD5A1 | c.686dup p.L229Ffs*4 | Frame Shift Ins (INS) | VAF 21/92 reads (23%) | called by mutect2, pindel, varscan2
- ARHGAP45 | c.2568G>T p.L856= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV57433808, COSV57434617; called by muse, mutect2, varscan2
- CASP1 | c.492T>G p.L164= (on ENST00000436863 / NM_033292.4; = p.L143= on NM_001223.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV62057027; called by mutect2, varscan2
- DYM | c.1149G>C p.L383= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV53988304, COSV53993529; called by muse, mutect2, varscan2
- G2E3 | c.1593G>A p.T531= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as COSV52841562; called by muse, mutect2, varscan2
- GTF3C1 | c.498G>A p.E166= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100649934, COSV62239767, COSV62242697; called by muse, mutect2, varscan2
- IL31RA | c.2169T>C p.G723= | Silent (SNP) | VAF 43/150 reads (29%) | catalogued as COSV61695392; called by muse, mutect2, varscan2
- MESP2 | c.1191C>T p.Y397= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as rs375171689; called by muse, mutect2, varscan2
- NDST1 | c.1824C>T p.L608= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV55788735; called by muse, mutect2, varscan2
- TRIP13 | c.690C>T p.T230= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV51320670; called by muse, mutect2, varscan2
- UPF3B | c.483A>G p.R161= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV52230720; called by muse, mutect2, varscan2
- USHBP1 | c.1476C>T p.A492= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV53104792; called by muse, mutect2, varscan2
- VCX3A | c.303C>T p.H101= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs773772687, COSV66910730; called by muse, mutect2
